Gene-level copy-number profile of specimen HCM-WCMC-0786-C34-85A from HCMI case HCM-WCMC-0786-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 76.8 years (28,050 days).
Specimen HCM-WCMC-0786-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0e839bd0-1a15-4d5f-9e69-9fd1c94e2424.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0786-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/e0e29dbe-6595-494c-b273-d22a06435a9a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,049; copy number 2: 53,856; copy number 3: 1,011.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,193. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
